Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4995, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4995-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

CGA-BP-4995

Original Diagnosis & History:

Male with a mid upper pole renal mass, right.

Specimens Submitted:

- 1: SP: KIDNEY AND ADRENAL GLAND, RIGHT, NEPHRECTOMY AND PARTIAL ADRENALECTOMY
- 2: SP: 11TH RIB, RIGHT, PARTIAL RESECTION
- 3: SP: ADRENAL GLAND, PARTIAL RESECTION
- 4: SP: ADRENAL GLAND, RIGHT, PARTIAL RESECTION
- 5: SP: LYMPH NODES, RIGHT PARAAORTIC, RESECTION

DIAGNOSIS:

1. SP: KIDNEY AND ADRENAL GLAND, RIGHT, NEPHRECTOMY AND PARTIAL ADRENALECTOMY

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 4.6 cm.

Local Invasion (for renal cortical types):

Not identified

tumor abuts but does not involve renal sinus fat

Renal Vein Invasion:

Tumor extends into muscularized branches of the renal vein in the renal sinus region

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

mild chronic interstitial nephritis

Adrenal Gland:

Not involved

Also see parts 3 and 4

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

2. SP: 11TH RIB, RIGHT, PARTIAL RESECTION [REDACTED]
- BENIGN BONE AND HEMATOPOIETIC BONE MARROW ELEMENTS.
3. SP: ADRENAL GLAND, PARTIAL RESECTION [REDACTED]
- PORTION OF BENIGN ADRENAL GLAND.
4. SP: ADRENAL GLAND, RIGHT, PARTIAL RESECTION [REDACTED]
- PORTION OF BENIGN ADRENAL GLAND.
5. SP: LYMPH NODES, RIGHT PARAAORTIC, RESECTION [REDACTED]
- FIVE BENIGN LYMPH NODES, (0/5).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result	Special Stain	Comment
	RECUT-A	

Gross Description:

[REDACTED]

1). The specimen is received fresh, labeled "right kidney and part of adrenal" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 780 g in total. A portion of adrenal gland is also present on the specimen which measures 1.6 x 0.9 cm. The kidney measures 10.3 x 6 x 5 cm. The attached ureter measures 6.5 cm in length and 0.3 cm in diameter. The attached renal vein measures 0.5 cm in length and 1.0 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. The kidney is inked black and bivalved to reveal a 4.6 x 2.7 x 2.5 cm well defined, orange-yellow tumor in the upper half of the kidney. Sectioning through the tumor reveals a soft, variegated cut surface. Grossly, the tumor appears to extend into the renal vein and abuts but does not invade the renal pelvis. Sections through the remainder of the kidney reveal a pink-brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for [REDACTED] and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

TV -- tumor with renal vein

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

TRP -- tumor with adjacent renal pelvis

RP -- renal pelvis representative sections

K -- representative sections kidney

AD -- adrenal gland

[REDACTED]

2). The specimen is received in formalin, labeled "portion of 11th rib, right side" and consists of a portion of bone measuring 4.0 x 0.9 x 0.4 cm in greatest dimensions. Representative sections are submitted for decalcification.

Summary of sections:

[page 3 of 4]
U - undesignated

3). The specimen is received in formalin, labeled "piece of adrenal gland" and consists of a 1.3 x 0.6 x 0.1 cm fragment of orange-yellow soft tissue. Entirely submitted.

Summary of sections:

U - undesignated

4). The specimen is received in formalin, labeled "portion of right adrenal gland" and consists of a segment of yellow fibroadipose tissue with a portion of adrenal gland attached. The entire specimen measures 5.0 x 2.8 x 1.3 cm. The adrenal gland portion measures 3.8 x 2.2 cm. Representative sections are submitted.

Summary of sections:

U - undesignated

5). The specimen is received in formalin, labeled "right paraaortic lymph nodes" and consists of a few possible lymph nodes measuring from 0.3 to 1.0 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

Summary of Sections:

Part 1: SP: KIDNEY AND ADRENAL GLAND, RIGHT, NEPHRECTOMY AND PARTIAL ADRENALECTOMY

Block	Sect. Site	PCs
1	AD	1
2	K	2
1	RP	1
4	T	4
1	THF	1
1	TK	1
1	TRP	1
1	TSF	1
1	TV	1
1	UVM	1

Part 2: SP: 11TH RIB, RIGHT, PARTIAL RESECTION

Block	Sect. Site	PCs
1	U	1

Part 3: SP: ADRENAL GLAND, PARTIAL RESECTION

Block	Sect. Site	PCs
1	U	1

Part 4: SP: ADRENAL GLAND, RIGHT, PARTIAL RESECTION

Block	Sect. Site	PCs
1	U	1

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Part 5: SP: LYMPH NODES, RIGHT PARAAORTIC, RESECTION

Block	Sect. Site	PCs
1	In	1

Source: NCI Genomic Data Commons file 7b6e8bfb-2dd5-4c6e-b2dc-92d360d67edd (TCGA-BP-4995.D98BF5CD-A8A2-436E-9C05-B6225069504B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).